Somatic mutation profile of tumor specimen 0DN9EO from CCDI case PBCBGY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 22.6 years (8,252 days).
Specimen 0DN9EO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c0b4004-5802-4224-b5c7-f6953d8bcddb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DN9EW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d1b428f7-93ed-47da-ac35-adf02ca1eebc

The open-access MAF lists 24 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 4, Frame Shift Ins 2, Nonsense Mutation 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD7 | c.8962dup p.D2988Gfs*2 | Frame Shift Ins (INS) | VAF 154/344 reads (45%) | catalogued as rs771806027, CI084262; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- EIF1AX | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 210/419 reads (50%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen possibly damaging (0.693); catalogued as COSV63309291, COSV63309392, COSV63309466; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 129/275 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANKS1A | c.2674G>A p.A892T | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.045); catalogued as rs910088133; called by muse, mutect2, varscan2
- FARP1 | c.1813C>T p.R605* | Nonsense Mutation (SNP) | VAF 78/289 reads (27%) | catalogued as rs1227162641; called by muse, mutect2, varscan2
- IFI44 | c.397C>G p.L133V | Missense Mutation (SNP) | VAF 235/493 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV66075530; called by muse, mutect2, varscan2
- LGI1 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 124/296 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.042); catalogued as rs772228851, COSV65058047; called by muse, mutect2, varscan2
- LPA | c.3332G>A p.R1111H | Missense Mutation (SNP) | VAF 91/274 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.897); catalogued as rs538344206, COSV60301564; called by muse, mutect2, varscan2
- NDN | c.197A>G p.D66G | Missense Mutation (SNP) | VAF 58/95 reads (61%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.861); catalogued as COSV59359467; called by muse, mutect2, varscan2
- PCDH8 | c.1205C>G p.P402R | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as rs1278442287; called by muse, mutect2, varscan2
- PLEC | c.12437G>A p.R4146H (on ENST00000322810 / NM_201380.4; = p.R4036H on NM_000445.5) | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs564907731; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPRY3 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 117/249 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs746190550, COSV57143419; called by muse, mutect2, varscan2
- TBX15 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 161/335 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.035); catalogued as rs1204402285; called by muse, mutect2, varscan2
- TNN | c.3869G>A p.R1290Q | Missense Mutation (SNP) | VAF 147/342 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs1324887927, COSV53427795; called by muse, mutect2, varscan2
- UPF1 | c.1598C>T p.P533L (on ENST00000599848 / NM_001297549.2; = p.P522L on NM_002911.4) | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1568279022, COSV53194164; called by muse, mutect2, varscan2
- BRWD3 | c.4652A>T p.Q1551L | Missense Mutation (SNP) | VAF 140/348 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- OR9G1 | c.809A>G p.D270G | Missense Mutation (SNP) | VAF 233/815 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- PRPF39 | c.1145_1147del p.S382del | In Frame Del (DEL) | VAF 146/318 reads (46%) | called by mutect2, varscan2
- TRAF2 | c.1452_1453insA p.V485Sfs*249 | Frame Shift Ins (INS) | VAF 144/152 reads (95%) | called by mutect2, varscan2
- HIVEP1 | c.516C>T p.T172= | Silent (SNP) | VAF 165/365 reads (45%) | called by muse, mutect2, varscan2
- IFI16 | c.252A>G p.K84= | Silent (SNP) | VAF 78/255 reads (31%) | catalogued as COSV55539053; called by muse, mutect2, varscan2
- PELP1 | c.1557C>T p.S519= | Silent (SNP) | VAF 63/131 reads (48%) | catalogued as rs372215978; called by muse, mutect2, varscan2
- ZNF865 | c.1590C>T p.L530= | Silent (SNP) | VAF 70/136 reads (51%) | called by muse, mutect2, varscan2
- COCH | c.1155+76C>T | Intron (SNP) | VAF 48/99 reads (48%) | called by muse, mutect2, varscan2
